Surgical pathology report (de-identified scan), TCGA case TCGA-CS-4941, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Thomas Jefferson University, specimen TCGA-CS-4941-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED] TCGA-CS-4941

FINAL DIAGNOSIS:

right brain tumor frontal lobe: anaplastic astrocytoma, grade III of IV (WHO scale), see microscopic description

[REDACTED]

Report Electronically Signed

This diagnostic report has been personally interpreted by the signatory of record.

[REDACTED]

Microscopic Description:

The tumor consists of a highly cellular and markedly pleomorphic proliferation of astrocytic cells. There are scattered mitoses. There is no endothelial proliferation or necrosis. The findings are diagnostic of an anaplastic astrocytoma, grade III of IV (WHO scale).

Frozen Section Diagnosis:

1. High grade glioma

Clinical History and Diagnosis:

Right frontal lobe brain tumor, rule out glioma, history of migraines

Source of Specimen:

- 1: Right brain tumor frontal lobe

Gross Description:

- [REDACTED]
1. Right brain tumor frontal lobe: Received fresh is a 1.5 x 1.3 x

[page 2 of 2]
(cm aggregate of soft tan-pink tissue. Touch preparations are prepared. Touch preparations were used in conjunction with and complemented frozen sections to establish the frozen section diagnosis.

Approximately 50% of the specimen is submitted for frozen section.

The specimen is entirely submitted in two cassettes as follows:

A: Frozen section control

B: Remainder of specimen

Histology Laboratory

H&E

Source: NCI Genomic Data Commons file 0702cbcf-82f5-4c1f-b0a0-c3f12ad2cf32 (TCGA-CS-4941.D76D3BEA-149D-4B82-87CE-0D0541BB9DD5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).